CCDI case PBBRCW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/0d20368b-d47a-4e03-9a92-2297ed221e47

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 17.1 years (6,257 days).

Biospecimens (4 samples)
- Sample 0DLHO4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLHOE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DLHOP, 0DLHOU (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
